TARGET case TARGET-15-SJMPAL017975 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f69bae74-07b6-40ec-9779-7c229ac93796

Demographics
Sex at birth: male; Age at index: 17 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 17.9 years (6,527 days); Year of diagnosis: 1986; Days to last follow up: 2,927 days (8.0 years).

Follow-up (1 entry)
- Days to follow up: 2,927 days (8.0 years); Event-free: no event (relapse, second malignancy or death) recorded through day 2,927; Year of follow up: 1994.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 14.9 ×10³/µL.

Biospecimens (5 samples)
- Samples TARGET-15-SJMPAL017975-03A, TARGET-15-SJMPAL017975-03A.1, TARGET-15-SJMPAL017975-03A.2, TARGET-15-SJMPAL017975-03B (4 with the same recorded description): Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
- Sample TARGET-15-SJMPAL017975-10A.1: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 2927
- Protocol: St. Jude
- WBC at Diagnosis: 14.9
- Initial Therapy: AML
- Karyotype: 51,XY,+Y,+4,+6,+13,+22[18]
- WHO ALAL Classification: B/M
- WHO Dx: B/M
